Somatic mutation profile of tumor specimen HCM-CSHL-0061-C18-01A (aliquot HCM-CSHL-0061-C18-01A-01D-A768-36) from HCMI case HCM-CSHL-0061-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,277 days).
Specimen HCM-CSHL-0061-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac3a8d78-e2bb-42d5-b002-a39d0158fb8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0061-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0061-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78241b89-8fcc-47af-bd08-51cd2c22176c

The open-access MAF lists 130 somatic variants for this specimen: 98 protein-altering or splice-affecting, 24 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 24, Nonsense Mutation 5, RNA 3, Frame Shift Del 2, 5'Flank 2, Intron 2, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 144/376 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC099489.1 | c.4183G>A p.V1395M | Missense Mutation (SNP) | VAF 67/646 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as rs1311438842, COSV60865433; called by muse, mutect2, varscan2
- ACR | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455933339, COSV53361696; called by muse, mutect2
- AMY2A | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1276826607; called by mutect2, varscan2
- ATP13A3 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1271200464; called by muse, mutect2
- BRINP3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs144952455, COSV66521744; called by muse, mutect2, varscan2
- CEND1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs762710448, COSV57192414; called by muse, mutect2, varscan2
- CEP128 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs115620263; called by muse, mutect2, varscan2
- COL5A1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs768531108, COSV65673999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSDE1 | c.911C>T p.T304M (on ENST00000358528 / NM_001007553.3; = p.T273M on NM_007158.6) | Missense Mutation (SNP) | VAF 49/343 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs542388231, COSV54755638; called by muse, mutect2, varscan2
- DACT1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 237/420 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773256045; called by muse, mutect2, varscan2
- DCBLD1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 70/656 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs779698146; called by muse, mutect2
- DGKB | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51775651; called by muse, mutect2, varscan2
- DNAI2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as rs752440806, COSV56761525; called by muse, mutect2, varscan2
- DNASE1L1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs781833694; called by muse, mutect2, varscan2
- FAM47B | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 146/596 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs778028004, COSV61453478; called by muse, mutect2, varscan2
- FAT2 | c.9778G>A p.E3260K | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs758791616, COSV55823617; called by muse, mutect2, varscan2
- FLNC | c.5984G>A p.R1995H | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs371508414; ClinVar: uncertain significance; called by muse, mutect2
- GABRA3 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100943343; called by muse, mutect2, varscan2
- GLI3 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 148/691 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as rs529978440; called by muse, mutect2, varscan2
- GRIN2D | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.607); catalogued as rs1382484564; called by muse, mutect2, varscan2
- HIP1R | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs749364683; called by muse, mutect2, varscan2
- HMCN2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1286308441, COSV70279975; called by muse, mutect2, varscan2
- INF2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 199/792 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.169); catalogued as rs1049200069, COSV99383740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCF1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763053117, COSV58823313; called by muse, mutect2
- KRTAP4-3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs371581214; called by muse, mutect2, varscan2
- LRRC37A2 | c.3482G>A p.R1161Q | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs753899745, COSV61003345; called by muse, varscan2
- MSI1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1210006090; called by muse, mutect2, varscan2
- MYLK3 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV101189128; called by muse, mutect2, varscan2
- OR4A5 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 152/426 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV60521838; called by muse, mutect2, varscan2
- OTOF | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs149701372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFRA | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as rs774431464, COSV57265740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZD7 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1173857385; called by muse, mutect2, varscan2
- PID1 | c.212C>T p.P71L (on ENST00000354069 / NM_001330156.1; = p.P69L on NM_017933.5) | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs766470127, COSV62476119; called by muse, mutect2, varscan2
- PMFBP1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as rs778219933; called by muse, mutect2, varscan2
- PROM2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs537196418, COSV100469102, COSV100469421; called by muse, mutect2, varscan2
- REM1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52427424; called by muse, mutect2, varscan2
- RGPD3 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 125/1524 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs763265166; called by muse, mutect2
- RP1 | c.4523A>G p.D1508G | Missense Mutation (SNP) | VAF 166/540 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs751429007; called by muse, varscan2
- SACM1L | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613346; called by muse, mutect2, varscan2
- SLC8A2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 44/398 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761837734, COSV52638361; called by muse, mutect2, varscan2
- STK10 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs757877605, COSV51571147; called by muse, mutect2, varscan2
- TBC1D8B | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 24/218 reads (11%) | catalogued as rs749688361; called by muse, mutect2
- TMEM132D | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV70593364; called by muse, mutect2, varscan2
- TOP1MT | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 258/438 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563952364; called by muse, mutect2, varscan2
- TRIM67 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1402267120; called by muse, varscan2
- WNT3A | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.455); catalogued as rs1399260520; called by muse, mutect2, varscan2
- ZC4H2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs958668037, COSV100565132, COSV62002663; called by muse, mutect2, varscan2
- ZNF213 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1410444742; called by muse, mutect2
- ZNF345 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV59323810, COSV59325519; called by muse, mutect2, varscan2
- ZNF397 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1203968566; called by muse, mutect2, varscan2
- ABCA9 | c.1714G>T p.G572* | Nonsense Mutation (SNP) | VAF 45/314 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.3384C>G p.S1128R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- APC | c.4063dup p.S1355Ffs*20 | Frame Shift Ins (INS) | VAF 156/406 reads (38%) | called by pindel, varscan2
- ARID1A | c.2427C>A p.Y809* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- CBX5 | c.138-3C>G | Splice Region (SNP) | VAF 121/342 reads (35%) | called by muse, mutect2, varscan2
- CEP126 | c.248del p.A84Lfs*57 | Frame Shift Del (DEL) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.1962G>T p.R654S | Missense Mutation (SNP) | VAF 72/663 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- DISP1 | c.2622C>G p.C874W | Missense Mutation (SNP) | VAF 164/561 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIZ1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GUCY2C | c.523T>A p.W175R | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HECTD4 | c.6545G>A p.G2182E | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HECTD4 | c.6544G>A p.G2182R | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPRID1 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- LIN9 | c.1275G>C p.M425I (on ENST00000366808 / NM_001270410.2; = p.M370I on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRIG3 | c.2599A>T p.R867W | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRP1B | c.12995C>A p.S4332Y | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MANEA | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MARCHF8 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAST2 | c.2270A>G p.D757G | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MED14 | c.4331C>T p.A1444V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MNDA | c.611G>T p.R204I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MROH5 | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR0B1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 106/563 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- NRK | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.671); called by muse, mutect2
- NRXN1 | c.2930_2933del p.G977Afs*14 | Frame Shift Del (DEL) | VAF 32/162 reads (20%) | called by mutect2, pindel, varscan2
- ODF2L | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD4 | c.2388C>G p.I796M (on ENST00000447906 / NM_001366057.1; = p.I731M on NM_001102653.1) | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PALB2 | c.3427C>A p.L1143I | Missense Mutation (SNP) | VAF 60/496 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PCDHB15 | c.2299T>A p.L767M | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); called by muse, mutect2
- PCDHGA5 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PKD1 | c.9070G>A p.V3024M | Missense Mutation (SNP) | VAF 101/849 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLAGL2 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PSME4 | c.2943+1G>T p.X981_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- RFX6 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, varscan2
- RIPK4 | c.2330A>G p.D777G (on ENST00000352483; = p.D729G on NM_020639.3) | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- RUBCNL | c.147C>G p.H49Q | Missense Mutation (SNP) | VAF 73/553 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SAP30BP | c.152T>C p.F51S | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SENP7 | c.2047T>G p.C683G | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SORCS3 | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SUGP1 | c.1696G>T p.G566C | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANC2 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 76/567 reads (13%) | called by muse, mutect2, varscan2
- TLE1 | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS11 | c.898C>G p.Q300E (on ENST00000620429; = p.Q844E on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/526 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- XIRP1 | c.2726C>G p.A909G | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ZC3H18 | c.683T>G p.M228R | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZNF600 | c.1022G>A p.W341* | Nonsense Mutation (SNP) | VAF 149/417 reads (36%) | called by muse, mutect2, varscan2
- ZW10 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ACOXL | c.630C>T p.S210= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as rs776875130; called by muse, mutect2, varscan2
- ANKFN1 | c.3264C>T p.D1088= (on ENST00000653862; = p.D941= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 181/563 reads (32%) | catalogued as rs1297126836, COSV73718981; called by muse, mutect2, varscan2
- C3orf18 | c.210G>A p.T70= | Silent (SNP) | VAF 61/318 reads (19%) | catalogued as rs768800486, COSV99231943, COSV99232014; called by muse, mutect2, varscan2
- CELSR3 | c.3114C>T p.Y1038= | Silent (SNP) | VAF 77/300 reads (26%) | catalogued as rs778090405, COSV50882888; called by muse, mutect2, varscan2
- CES4A | c.489G>T p.V163= | Silent (SNP) | VAF 103/499 reads (21%) | called by muse, mutect2, varscan2
- CES4A | c.1029G>T p.V343= | Silent (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- CHRNB3 | c.519C>A p.S173= | Silent (SNP) | VAF 44/672 reads (7%) | called by muse, mutect2
- COL22A1 | c.1518G>A p.P506= | Silent (SNP) | VAF 42/596 reads (7%) | catalogued as rs575514821, COSV57342112; called by muse, mutect2
- COPZ2 | c.321C>T p.D107= | Silent (SNP) | VAF 18/261 reads (7%) | catalogued as COSV50058430; called by muse, mutect2
- CSF2RA | c.231C>T p.N77= | Silent (SNP) | VAF 215/527 reads (41%) | catalogued as rs767927197, COSV62623442; called by muse, mutect2, varscan2
- ENG | c.1329C>T p.L443= | Silent (SNP) | VAF 78/673 reads (12%) | catalogued as COSV61229076; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1386C>T p.H462= | Silent (SNP) | VAF 54/259 reads (21%) | catalogued as rs561419730; called by muse, mutect2, varscan2
- FLNA | c.210C>T p.D70= | Silent (SNP) | VAF 168/531 reads (32%) | called by muse, mutect2, varscan2
- FRMPD3 | c.933G>A p.A311= | Silent (SNP) | VAF 29/461 reads (6%) | catalogued as rs184794832; called by muse, mutect2
- GTF2A2 | c.99C>T p.A33= | Silent (SNP) | VAF 59/168 reads (35%) | called by muse, mutect2, varscan2
- HIPK1 | c.510C>T p.S170= | Silent (SNP) | VAF 48/295 reads (16%) | catalogued as rs368795005; called by muse, mutect2, varscan2
- IRX4 | c.93C>G p.G31= | Silent (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- PCDHB15 | c.2301G>A p.L767= | Silent (SNP) | VAF 40/246 reads (16%) | called by muse, mutect2
- PLXNA4 | c.1755G>A p.P585= | Silent (SNP) | VAF 103/433 reads (24%) | catalogued as rs749277155, COSV58142069; called by muse, mutect2, varscan2
- PRR32 | c.690G>A p.P230= | Silent (SNP) | VAF 107/373 reads (29%) | catalogued as rs1187927699, COSV100947888, COSV64420750; called by muse, mutect2, varscan2
- PRR33 | c.1326C>T p.N442= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs750539867; called by muse, mutect2, varscan2
- SYT9 | c.81C>T p.H27= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as COSV100607733; called by muse, mutect2, varscan2
- TMEM132C | c.750C>T p.N250= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs775829161, COSV70659367; called by muse, mutect2, varscan2
- WDR45 | c.1047C>T p.D349= (on ENST00000376372 / NM_001029896.2; = p.D350= on NM_007075.3) | Silent (SNP) | VAF 49/257 reads (19%) | catalogued as rs376872853, COSV59876345; called by muse, mutect2, varscan2
- CCDC39 | chr3:180679793 C>T | 5'Flank (SNP) | VAF 16/126 reads (13%) | catalogued as rs1290651415; called by muse, mutect2
- FOCAD | c.57+763T>G | Intron (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- GUSBP1 | n.180-10268C>A | Intron (SNP) | VAF 90/2707 reads (3%) | called by muse, mutect2
- MMADHC | c.-44_-43del | 5'UTR (DEL) | VAF 65/270 reads (24%) | called by mutect2, pindel, varscan2
- MYADML | n.996G>A | RNA (SNP) | VAF 46/340 reads (14%) | catalogued as rs750520177; called by muse, varscan2
- OR2H2 | chr6:29582314 T>A | 5'Flank (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- PMS2CL | n.1276G>A | RNA (SNP) | VAF 40/466 reads (9%) | catalogued as rs535681432; called by muse, mutect2
- PRSS30P | n.2781C>T | RNA (SNP) | VAF 94/309 reads (30%) | catalogued as rs778932607; called by muse, mutect2, varscan2
